Surgical pathology report (de-identified scan), TCGA case TCGA-36-2533, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site BC Cancer Agency, specimen TCGA-36-2533-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Consultation Report

TCGA-36-2533

Case Number:

Collect Date:

Receive Date:

Date Reported:

Patient's Name:

MRN:

PHN:

DOB/Gender:

Ordering
Physician:

Final Diagnosis:

1. Omentum, excision: A 6 mm nodule of metastatic high-grade papillary serous carcinoma.
2. Right ovary and tube, right salpingo-oophorectomy specimen showing:
- A. Ovary essentially replaced by high-grade papillary serous carcinoma measuring approximately 9.0 cm in maximum dimension.
- B. Outer surface of ovary is studded with tumor.
- C. Lymphatic invasion identified.
- D. Fallopian tube is negative for carcinoma.
3. Left ovary and tube, left salpingo-oophorectomy specimen showing:
- A. Ovary essentially replaced by high-grade papillary serous carcinoma measuring approximately 9.0 cm in maximum dimension.
- B. Fallopian tube is negative for malignancy.
- C. Tumor extensively involves the surface of the ovary.
- D. Lymphatic invasion identified.
4. Uterus and cervix, hysterectomy specimen showing:
- A. A single focus of tumor in the section from the cul-de-sac.
- B. Benign inactive endometrium, negative for tumor.

[page 2 of 4]
- C. The cervix shows benign ecto and endocervical epithelium, negative for malignancy.
- D. A 1 mm leiomyoma within the cervix.

5. "Peritoneal implants from pelvis", biopsy:

- A. Positive for high-grade papillary serous carcinoma.
- B. Stage 2C.

[REDACTED]

[REDACTED]

Clinical History as Provided by Submitting Physician:
?ov cancer

- [REDACTED]
- A. Omentum
- B. (R) ovary and tube
- C. (L) ovary and tube
- D. Uterus and cervix
- E. Peritoneal implants from pelvis

Specimens Received:

- A: omentum
- B: right ovary & tubes
- C: left ovary & tubes
- D: uterus and cervix
- E: peritoneal implants from pelvis

Gross Description:

The specimen is received in five containers all labelled with the patient's demographics.

Specimen "A" is labelled "omentum". It consists of a portion of omentum measuring 24 x 15 x 1.5 cm. The omentum is serially sectioned from one end to the other revealing a white-coloured, solid nodule, 0.6 cm in diameter. No other nodules identified grossly.

Representative sections are submitted as follows:

- A1 -nodule in omentum
- A2-A6 -representative sections of the omentum

Specimen "B" is labelled "right ovary and tube". It consists of an enlarged ovary and attached fallopian tube with a total weight of 158 g. The fallopian tube measures 6.5 cm

[page 3 of 4]
in length x 0.6 cm in diameter. The ovary measures 9 x 8.5 x 6 cm. The entire outer surface of the ovary is covered by papillary tumour deposits with cauliflower-like appearance. Cut sections reveal multilocular cysts ranging from 1-4 cm in diameter with solid areas in their walls and some papillary projections. Some of the cysts contain gelatinous material. A piece was submitted for frozen section.

Representative sections are submitted as follows:

- B1 -piece sampled for frozen section
- B2 -right fallopian tube
- B3,B4 -right ovary, surface involvement by tumour
- B5 -right ovary, papillary area
- B6,B7 -right ovary, solid areas
- B8,B9 -right ovary, solid and cystic areas
- B10 -right ovary, cystic area

Specimen "C" is labelled "left ovary and tube". The specimen is a left salpingo-oophorectomy weighing 116 g, consisting of ovary (9 x 6.5 x 4 cm) and fallopian tube (5 cm in length x 1.4 cm in diameter). Similar to the right ovary, the left ovary has extensive involvement of the serosal surface by papillary tumour with cauliflower-like appearance. The ovary is also multilocular with mainly solid areas and some papillary areas in the cyst walls.

Representative sections are submitted as follows:

- C1 -left fallopian tube
- C2,C3 -left ovary, surface involvement by tumour
- C4-C6 -left ovary, solid areas
- C7,C8 -left ovary, solid and cystic areas
- C9 -left ovary, solid and papillary area

Specimen "D" is labelled "uterus and cervix". The specimen is a hysterectomy weighing 42.4 g and measuring 6 cm (superior to inferior) x 4 cm (cornu to cornu) x 3 cm (anterior to posterior). The ectocervix is covered by white glistening mucosa. The serosal surface of the uterus is smooth and shiny. The endocervical canal (2 cm in length) is unremarkable. The endometrial cavity (4 cm in length x 2.5 cm cornu to cornu) has a tan-coloured lining with no remarkable abnormality grossly. The myometrial wall is up to 1.5 cm in thickness. There is an elevated area in the anterior endometrium measuring 1 cm in maximum dimension.

Representative sections are submitted as follows:

- D1 -cul-de-sac
- D2 -anterior cervix
- D3 -posterior cervix
- D4 -lower uterine segment, anterior
- D5 -lower uterine segment, posterior
- D6,D7 -anterior uterine wall
- D8,D9 -posterior uterine wall

[page 4 of 4]
Specimen "E" is labelled "peritoneal implants from pelvis". It consists of two fragments of hemorrhagic tissue, the smaller of which measures 0.7 cm in maximum dimension and the larger 1 cm in maximum dimension. Bisected and submitted in toto in cassette E1.

Intraoperative Consultation:

FSB1: GROSS: Rt ovary and tube 9 x 6 x 5 cm red-grey papillary/cystic mass with central yellow solid area. 158 g. Tissue sampled for .

PROVISIONAL DIAGNOSIS: High-grade carcinoma, favour serous differentiation.

FSC1: GROSS: Lt ovary and tube 9 x 6.5 x 30 cm, 116 g

PROVISIONAL DIAGNOSIS:

Source: NCI Genomic Data Commons file 3ede11b5-6e45-4b7c-911a-fc28abfcf1ea (TCGA-36-2533.EBE9DFC0-28AC-4D22-A18B-B910AA2814E0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).